TARGET case TARGET-10-PASUIN — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8922080-e02b-5a5e-858f-37d904dc223d

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander; Ethnicity: not hispanic or latino; Age at index: 13 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 13.7 years (5,004 days); Year of diagnosis: 2009; Days to last follow up: 2,564 days (7.0 years).
   Treatment given: Protocol identifier: AALL0434.

Follow-up (2 entries)
- Days to follow up: 2,243 days (6.1 years); Days to first event: 2,243 days (6.1 years); First event: Second Malignant Neoplasm.
- Days to follow up: 2,564 days (7.0 years); Year of follow up: 2016.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 195 ×10³/µL; Bone Marrow blast count 83%.
- Day 8: Bone Marrow blast count 16%.
- Day 15: Bone Marrow blast count 4%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (2 samples)
- Sample TARGET-10-PASUIN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PASUIN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PASUIN-09A-01D:
- Blast %: 0.9

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 2564
- WBC at Diagnosis: 194.6
- CNS Status at Diagnosis: CNS 2a
- Testicular Involvement: No
- MRD Day 29: 0
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 16
- BMA Blasts Day 15: 4
- BMA Blasts Day 29: 0
- Karyotype: 46,XY,t(3;14)(p14;q32),del(9)(p12)[6]/46,XY[15]
- Down Syndrome: No
- DNA Index: 1
- Alternate Therapy: Chemotherapy
- Cell of Origin: T Cell ALL

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Validation_Supplement_20230727.xlsx:
- BM Blasts at Diagnosis: 83
- Group: NKX2_1
- Lesion: NKX2-1-TCRA
- ETP status: notETP
- Maturation stage: Cortical
